Surgical pathology report (de-identified scan), TCGA case TCGA-HW-7490, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-7490-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

History of thyroid carcinoma here today for resection of left occipital lesion.

Specimens Submitted:

1: Left occipital brain lesion biopsy

2: Left occipital brain tumor # 2

DIAGNOSIS:

1. Brain, left occipital lobe; biopsy:
- Diffuse astrocytoma, WHO grade II (see note)
2. Brain, left occipital lobe, # 2; resection:
- Diffuse astrocytoma, WHO grade II (see note)

Note: While we find some oligodendroglial features, this lesion is fundamentally astrocytic in appearance with widespread labeling of fibrillary cytoplasmic processes for GFAP as well as nuclear p53 expression by many tumor cells. Mib-1 labeling index does not exceed 2%. There is immunoexpression of R132H mutant IDH1.

Material will be forwarded to cytogenetics for 1p/19q analysis and to molecular diagnostics for IDH and MGMT studies.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain

Comment

IDH1-H09

P53

GFAP

MIB-1 (Ki-67)

IDH1-H09

P53

GFAP

IMM RECUT

NEG CONT

IMM RECUT

NEG CONT

RECUT

RECUT

MIB-1 (Ki-67)

[page 2 of 2]
Gross Description:

1). The specimen is received fresh, labeled "left occipital brain lesion biopsy". It consists of tan red soft tissue measuring 1 x 0.5 x 0.3 cm. A touch preparation is made and the specimen is submitted entirely for frozen section.

Summary of Sections:

FSC- frozen section control

2.) The specimen is received fresh, labeled "left occipital brain tumor #2" and consists of tan-white soft tissue measuring 3.5 x 2.5 x 1.5 cm. The specimen is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Left occipital brain lesion biopsy

Block	Sect. Site	PCs
1	FSC	1

Part 2: Left occipital brain tumor # 2

Block	Sect. Site	PCs
5	U	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Left occipital brain lesion biopsy Glioma
Permanent diagnosis: Same

Source: NCI Genomic Data Commons file 4b69f51f-62dc-41e2-b9b2-e8c43c92d3b1 (TCGA-HW-7490.D3358D25-968E-4814-8B2F-6D1203F1861A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).